Gene-level copy-number profile of tumor specimen TCGA-E7-A6ME-01A from TCGA case TCGA-E7-A6ME, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.8 years (27,670 days).
Specimen TCGA-E7-A6ME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6221f254-d2b8-45de-be2a-5e3672214fe5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A6ME-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1cf41c88-31d1-4255-9f8c-454e178caee5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 9,693; copy number 2: 40,583; copy number 3: 8,596; copy number 4: 375; copy number 5: 83; copy number 6: 244; copy number 7: 54; copy number 8: 56; copy number 9: 66; copy number 12: 57; copy number 15: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A6ME-01A-22D-A32A-01): tumor purity 0.79, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:157,107,727–157,119,706, 1 gene: AL049820.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 562 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:104,487,095–107,459,564, 48 genes, copy number 7–9 (within-gene range 3–9): AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr14:21,990,496–26,806,467, 259 genes, copy number 6–15 (within-gene range 1–15) (broad region; genes not listed).
- chr16:8,674,596–13,240,416, 120 genes, copy number 5–12 (broad region; genes not listed).
- chr16:15,865,719–19,173,578, 86 genes, copy number 5–9 (broad region; genes not listed).
- chr16:23,061,406–23,149,270, 1 gene, copy number 8 (within-gene range 3–8): USP31.
- chr16:23,167,577–25,088,618, 48 genes, copy number 8 (within-gene range 4–8): AC099482.2, SCNN1G, AC099482.1, SCNN1B, COG7, RN7SKP23, SNORA75, AC008915.1, AC008915.2, GGA2, CCNYL7, EARS2, SUB1P4, UBFD1, AC008870.2, NDUFAB1, PALB2, AC008870.4, DCTN5, AC008870.1, PLK1, AC008870.3, ERN2, AC008870.5, AC012317.1, AC012317.2, CHP2, PRKCB, AC130454.1, AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4.

Autosomal genes at a single copy (total copy number 1): 7,313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
